Somatic mutation profile of tumor specimen TCGA-CR-6488-01A (aliquot TCGA-CR-6488-01A-12D-2078-08) from TCGA case TCGA-CR-6488, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 68.9 years (25,176 days).
Specimen TCGA-CR-6488-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20bf30a2-69a6-403b-a99a-520825031397.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6488-10A (Blood Derived Normal), aliquot TCGA-CR-6488-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77d6c8fd-64df-4df9-b852-d2c036983b6d

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 11, Nonsense Mutation 4, Splice Region 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.3104C>T p.S1035F | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1297750901, COSV52203452; called by muse, mutect2
- ART5 | c.574C>A p.H192N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100731736, COSV63364485; called by muse, mutect2, varscan2
- CFAP47 | c.1272T>G p.C424W | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936001; called by muse, mutect2
- DELE1 | c.1150-1G>T p.X384_splice | Splice Site (SNP) | VAF 15/109 reads (14%) | catalogued as COSV52006452; called by muse, mutect2, varscan2
- EDIL3 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56904239; called by muse, mutect2, varscan2
- FOXP4 | c.2014G>A p.E672K (on ENST00000307972 / NM_001012426.1; = p.E659K on NM_138457.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as COSV100333108; called by muse, mutect2
- GRN | c.1694G>T p.C565F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99275136, COSV99275204; called by muse, mutect2, varscan2
- H4-16 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV100797701; called by muse, mutect2, varscan2
- HEPH | c.1267C>T p.R423* (on ENST00000343002; = p.R156* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs1484807584, COSV57966686; called by muse, mutect2, varscan2
- HIF1AN | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100142900; called by muse, mutect2, varscan2
- HMCN1 | c.10770G>A p.Q3590= | Splice Region (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99637642; called by muse, mutect2, varscan2
- IQUB | c.1875T>A p.C625* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100227440; called by muse, mutect2, varscan2
- KLRC2 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV101122773, COSV67899547; called by muse, mutect2, varscan2
- OCA2 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372899234, COSV100667606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4M1 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV100271587; called by muse, mutect2
- RASGRP2 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.413); catalogued as COSV100818384; called by muse, mutect2, varscan2
- RBM5 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV100762453, COSV100762552; called by muse, mutect2, varscan2
- RFX2 | c.1435A>T p.K479* | Nonsense Mutation (SNP) | VAF 33/144 reads (23%) | catalogued as COSV100354037; called by muse, mutect2, varscan2
- SOWAHD | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV59649821; called by muse, mutect2
- SOX18 | c.266T>G p.M89R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100450630; called by muse, mutect2, varscan2
- UGT1A7 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.329); catalogued as COSV60833583; called by muse, mutect2
- WNT10A | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs201578578; called by muse, mutect2, varscan2
- CWC25 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GGNBP2 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- ALPK1 | c.2607C>T p.H869= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs553837857, COSV51589956; called by muse, mutect2, varscan2
- CILP2 | c.1854G>A p.A618= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV99365327; called by muse, mutect2
- CYB5R2 | c.417G>T p.T139= | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as COSV100207619, COSV55087213; called by muse, mutect2, varscan2
- GCN1 | c.6930G>A p.L2310= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100326242; called by muse, mutect2, varscan2
- IL17RA | c.168C>T p.T56= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs766418851, COSV100083528; called by muse, mutect2, varscan2
- LPIN2 | c.2151A>T p.A717= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV99859127; called by muse, mutect2, varscan2
- MAGEB18 | c.339G>A p.S113= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1305966996, COSV57464369; called by muse, mutect2
- NOCT | c.675A>C p.L225= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV99763991; called by muse, mutect2, varscan2
- PCDHGB2 | c.1380C>T p.H460= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV99549341; called by muse, mutect2, varscan2
- RLF | c.2970G>A p.T990= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs549341072, COSV101035366; called by muse, mutect2, varscan2
- SEZ6L2 | c.1395C>T p.F465= (on ENST00000308713 / NM_001114099.3; = p.F395= on NM_012410.4) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs112977823, COSV58099217; called by muse, mutect2, varscan2
- DPP6 | c.*370C>T | 3'UTR (SNP) | VAF 12/85 reads (14%) | catalogued as rs774477355, COSV100128864; called by muse, mutect2, varscan2
